CCDI case PBBYWT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/76b3206d-e9b4-4aa1-88af-bb54c8c1a23d

Demographics
Sex at birth: male; Race: native hawaiian or other pacific islander.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 1.3 years (464 days).

Biospecimens (3 samples)
- Sample 0DL1T1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DL1T8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DL1TN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
